Surgical pathology report (de-identified scan), TCGA case TCGA-55-A48X, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-A48X-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY:

PROCEDURE DATE: RECEIVED DATE: REPORT DATE:

COPY TO: [REDACTED]

100-03

adenocarcinoma, NOS
814013

Site = lung, lower lobe
9-11-12 C34.3
RD

Pre-Op Diagnosis
Lung mass
Post-Op Diagnosis
Same
Clinical History
Nothing indicated on requisition
Gross Description:
Five parts

Container labeled "[REDACTED] 1 - level 10 lymph node left lung" is a 2.0 x 1.5 x 1.0 cm of gray black focally shaggy fleshy appearing tissue fragments entirely submitted in a single cassette.

Container labeled "[REDACTED] 2 - level 7 lymph node left lung" is a 0.8 x 0.6 x 0.3 cm of gray black fleshy tissue fragments entirely submitted in a single cassette.

Container labeled "[REDACTED] 3 - level 5 lymph node left lung" is a 1.1 x 0.8 x 0.3 cm of gray yellow to brown black fleshy and fibrofatty appearing tissue fragments which are entirely submitted in a single cassette.

Container labeled "[REDACTED] 4 - left lower lobe left lung" is a 129 gram previously partially sectioned portion of recognizable pulmonary parenchyma grossly consistent with left lower lobe of lung. The specimen as received is 15.0 x 7.9 x 12.0 cm and as its margin of resection multiple staple lines one of which appears to be a bifurcated tertiary bronchus. The pleura is slightly wrinkled tan pink with focal anthracotic streaking. The specimen has been partially sectioned at the apex to reveal a subpleural 2.6 x 2.2 x 1.9 cm previously sectioned nodular lesion with a gritty focally anthracotic streaked gray tan fibrotic cut surface. The lesion

[page 2 of 3]
grossly extends to but not through the pleura. This is noted at its nearest point 2.9 cm from the bronchial margin. An apparent bronchial connection is identified. The specimen is received after tissue harvest for genomic study. Within the specimen container are three tissue cassettes labeled [REDACTED] the remaining parenchyma is spongy pink red with moderate anthracotic streaking. No additional gross lesions are identified. Representative sections are submitted labeled as follows: A - shaved bronchial margin, B through E - remaining lesion and surrounding tissue, F - random uninvolved parenchyma.

Container labeled [REDACTED] 5 - level 6 lymph node left lung" is a 1.6 x 0.7 x 0.3 cm elongated portion of gray tan to pink yellow fleshy and fibroadipose tissue fragments which are entirely submitted in a single cassette.

Microscopic Description:

The slides labeled [REDACTED] are examined. See diagnosis.

Final Diagnosis

Left lung, left lower lobe (lobectomy):

Specimen integrity: Specimen intact, margins can be evaluated.

Specimen laterality: Left.

Tumor site: Left lower lobe.

Tumor size: 2.6 cm in greatest diameter.

Focality: Unifocal.

Histologic type: Adenocarcinoma.

Grade: Moderately differentiated.

Visceral pleural invasion: Not identified.

Tumor extension: Not identified.

Surgical margin status:

Bronchial margin: No carcinoma identified.

Vascular margin: Not applicable.

Parenchymal margin: Not applicable.

Parietal pleural margin: Not applicable.

Chest wall margin: Not applicable.

Visceral pleura: Carcinoma extends up to but not into and through visceral pleura.

Distance of invasive carcinoma from closest margin: Less than 1 mm from the visceral pleural margin.

Treatment effect: Unknown.

Lymphovascular space invasion: No unequivocal lymphovascular space invasion identified.

Lymph nodes: Carcinoma identified within one of two peribronchial lymph nodes (1/2) (see comment). See below diagnoses for remaining lymph nodes.

Other findings:

Emphysematous changes.

Left lung, level 10 lymph nodes:

Multiple fragments of lymph node demonstrating reactive sinus histiocytosis and anthrasilicosis, no metastatic carcinoma identified (see comment).

Left 7 lymph node, left lung:

Fragments of lymph node demonstrating reactive sinus histiocytosis and anthrasilicosis, no metastatic carcinoma identified.

Level 5 lymph node, left lung:

Fragments of lymph node demonstrating reactive sinus histiocytosis and anthrasilicosis, no metastatic carcinoma identified.

Level 6 lymph node, left lung:

[page 3 of 3]
Two fragments of lymph node demonstrating reactive sinus histiocytosis and anthrasilicosis, no metastatic carcinoma identified.

Stage: pT1b N1(see comment)

Comments

Two peribronchial lymph nodes were identified within specimen #4, the left lower lobe lobectomy. One of the two bronchial lymph nodes demonstrates a small focus of adenocarcinoma. Therefore, this is staged as a pN1.

The level 10 lymph nodes left lung, level 7 lymph nodes left lung, and level 5 lymph nodes left lung were all received fragmented and therefore an accurate node count cannot be performed.

An elastic stain was performed which demonstrates the adenocarcinoma to extend up to but not into or through the visceral pleura (with appropriate positive control).

At the request of the undersigned pathologist, these slides have been additionally reviewed by Dr. [REDACTED] who concurs with the diagnosis.

This report has been finalized at the [REDACTED]

<Sign Out Dr. Signature>
[REDACTED]

Reviewed Initials:	UM	

9/30/12

Source: NCI Genomic Data Commons file 6fb6173b-0ef3-4679-a493-7c39c0f24d6b (TCGA-55-A48X.4D06D10F-60F5-4417-BD8E-F2BBCA84BEEB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).